Somatic mutation profile of tumor specimen TCGA-XF-A8HC-01A (aliquot TCGA-XF-A8HC-01A-11D-A364-08) from TCGA case TCGA-XF-A8HC, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Papillary transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 79.4 years (28,996 days).
Specimen TCGA-XF-A8HC-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7b28ef7c-61d2-4847-a70f-5eb1fe75af2d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-XF-A8HC-10A (Blood Derived Normal), aliquot TCGA-XF-A8HC-10A-01D-A362-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2011e08e-7c8e-4f5a-b49a-9bbfb6404b04

The open-access MAF lists 164 somatic variants for this specimen: 106 protein-altering or splice-affecting, 53 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 87, Silent 53, Nonsense Mutation 11, Splice Site 3, Intron 2, Frame Shift Del 2, In Frame Del 2, 5'UTR 1, Frame Shift Ins 1, RNA 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ERBB2 | c.929C>T p.S310F | Missense Mutation (SNP) | VAF 108/218 reads (50%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1057519816, COSV54062198, COSV54062802; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCA8 | c.3646G>T p.E1216* | Nonsense Mutation (SNP) | VAF 15/84 reads (18%) | catalogued as COSV99067412, COSV99285303; called by muse, mutect2, varscan2
- ABCE1 | c.569G>A p.R190Q | Missense Mutation (SNP) | VAF 205/238 reads (86%) | SIFT tolerated (0.27); PolyPhen benign (0.015); catalogued as rs1168123937, COSV56849302; called by muse, mutect2, varscan2
- AP001781.2 | c.643C>A p.Q215K | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT tolerated, low confidence (0.78); PolyPhen benign (0); catalogued as COSV52791435; called by muse, mutect2, varscan2
- ARSH | c.207C>G p.I69M | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.292); catalogued as COSV66963948, COSV66963977; called by muse, mutect2, varscan2
- ASAP1 | c.3268G>A p.E1090K | Missense Mutation (SNP) | VAF 30/87 reads (34%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.995); catalogued as rs200013346; called by muse, mutect2, varscan2
- ASB3 | c.1382C>T p.S461F | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.76); catalogued as COSV55080769; called by muse, mutect2, varscan2
- C2CD5 | c.1406A>T p.Y469F | Missense Mutation (SNP) | VAF 29/60 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV61728281; called by muse, mutect2, varscan2
- C7 | c.1843G>A p.E615K | Missense Mutation (SNP) | VAF 27/99 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.076); catalogued as COSV57482376; called by muse, mutect2, varscan2
- CALB1 | c.323G>A p.R108K | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.992); catalogued as COSV55369957; called by muse, mutect2, varscan2
- CBWD3 | c.463G>A p.E155K | Missense Mutation (SNP) | VAF 15/152 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.217); catalogued as COSV100793931, COSV64133827; called by muse, mutect2
- CCDC88A | c.4358G>C p.G1453A | Missense Mutation (SNP) | VAF 25/46 reads (54%) | SIFT tolerated (0.38); PolyPhen benign (0.146); catalogued as COSV55071065, COSV99709946; called by muse, mutect2, varscan2
- CD2 | c.1009C>T p.P337S | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.614); catalogued as rs150484253; called by muse, mutect2, varscan2
- CHIA | c.106C>A p.P36T | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.278); catalogued as COSV58478771; called by muse, mutect2, varscan2
- CIAPIN1 | c.262C>T p.R88W | Missense Mutation (SNP) | VAF 56/123 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.715); catalogued as rs753740875, COSV67953480; called by muse, mutect2, varscan2
- CIR1 | c.265G>A p.E89K | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0.009); catalogued as rs767863653, COSV59598121; called by muse, mutect2, varscan2
- CLCNKA | c.1766T>A p.I589N | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.246); catalogued as COSV58894403; called by muse, mutect2, varscan2
- CNTN2 | c.1015G>A p.D339N | Missense Mutation (SNP) | VAF 27/53 reads (51%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.609); catalogued as rs1253351350, COSV59350782; called by muse, mutect2, varscan2
- COL1A2 | c.2330G>A p.R777H | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as rs746187799, COSV51967474; called by muse, mutect2, varscan2
- DCC | c.1519G>A p.E507K | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT tolerated (0.54); PolyPhen benign (0.011); catalogued as COSV59083747; called by muse, mutect2, varscan2
- DMAC2 | c.346C>T p.Q116* | Nonsense Mutation (SNP) | VAF 29/128 reads (23%) | catalogued as rs1160982192, COSV99700464; called by muse, mutect2, varscan2
- EIF3A | c.178G>A p.D60N | Missense Mutation (SNP) | VAF 44/68 reads (65%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as COSV64963768; called by muse, mutect2, varscan2
- EPHA7 | c.2957C>A p.A986E | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.983); catalogued as COSV65193260; called by muse, mutect2, varscan2
- EPPK1 | c.4051G>A p.E1351K | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.287); catalogued as rs377567910; called by muse, mutect2, varscan2
- ERBB3 | c.2815G>A p.D939N | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57264823; called by muse, mutect2, varscan2
- ERBB3 | c.3979G>T p.D1327Y | Missense Mutation (SNP) | VAF 52/179 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57246731, COSV57264850; called by muse, mutect2, varscan2
- FAM122B | c.412C>A p.P138T | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.006); catalogued as COSV53232714; called by muse, mutect2, varscan2
- FAM153B | c.880G>C p.E294Q (on ENST00000253490; = p.E217Q on NM_001265615.1) | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT tolerated, low confidence (0.4); PolyPhen possibly damaging (0.503); catalogued as COSV99498845; called by muse, mutect2, varscan2
- FAT3 | c.5897C>G p.S1966C | Missense Mutation (SNP) | VAF 31/84 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.325); catalogued as COSV53183479; called by muse, mutect2, varscan2
- G6PC3 | c.286C>T p.Q96* | Nonsense Mutation (SNP) | VAF 105/197 reads (53%) | catalogued as COSV99291193; called by muse, mutect2, varscan2
- GCLC | c.341A>G p.N114S (on ENST00000643939; = p.N118S on NM_001498.4) | Missense Mutation (SNP) | VAF 55/239 reads (23%) | SIFT tolerated (0.71); PolyPhen possibly damaging (0.511); catalogued as COSV57598208; called by muse, mutect2, varscan2
- GLS2 | c.220G>A p.D74N | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.171); catalogued as COSV61738566; called by muse, mutect2, varscan2
- GSTCD | c.1438C>T p.R480C (on ENST00000360505 / NM_001031720.3; = p.R393C on NM_024751.3) | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs754237074, COSV64732308; called by muse, mutect2, varscan2
- HS2ST1 | c.187C>T p.R63W | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.522); catalogued as rs368496293; called by muse, mutect2, varscan2
- HSPG2 | c.9658G>A p.E3220K | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT tolerated (0.59); PolyPhen probably damaging (0.983); catalogued as COSV65933233; called by muse, mutect2
- ITGB4 | c.703G>T p.G235C | Missense Mutation (SNP) | VAF 17/27 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs751671168, COSV52334038, COSV99564504; called by muse, mutect2, varscan2
- KIAA1210 | c.2251A>G p.T751A | Missense Mutation (SNP) | VAF 27/37 reads (73%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV68180674; called by muse, mutect2, varscan2
- KIFAP3 | c.1609G>C p.D537H | Missense Mutation (SNP) | VAF 41/102 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as rs1239056490, COSV63037893; called by muse, mutect2, varscan2
- KIFC2 | c.1837C>G p.P613A | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.53); PolyPhen benign (0.069); catalogued as rs757007735, COSV56762796, COSV56763278; called by muse, mutect2, varscan2
- KMT2E | c.4711C>T p.Q1571* | Nonsense Mutation (SNP) | VAF 12/80 reads (15%) | catalogued as COSV99996035; called by muse, mutect2, varscan2
- LAIR1 | c.241G>A p.E81K | Missense Mutation (SNP) | VAF 41/198 reads (21%) | SIFT tolerated (0.47); PolyPhen benign (0.196); catalogued as COSV57310309; called by muse, mutect2, varscan2
- LIMA1 | c.1802C>T p.S601F | Missense Mutation (SNP) | VAF 45/159 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV57966356, COSV57969049; called by muse, varscan2
- LMOD3 | c.1100A>T p.N367I | Missense Mutation (SNP) | VAF 26/189 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as CD1410739, COSV70456873; called by muse, mutect2, varscan2
- LMTK2 | c.400C>T p.R134C | Missense Mutation (SNP) | VAF 34/89 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs762521935, COSV52005390; called by muse, mutect2, varscan2
- LMTK3 | c.287C>T p.S96L | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV54313459; called by muse, mutect2
- LOXL4 | c.1106-1G>A p.X369_splice | Splice Site (SNP) | VAF 14/31 reads (45%) | catalogued as COSV53259711; called by muse, mutect2, varscan2
- LRP2 | c.161C>G p.S54* | Nonsense Mutation (SNP) | VAF 21/42 reads (50%) | catalogued as COSV99787389; called by muse, mutect2, varscan2
- LRP4 | c.2353G>A p.D785N | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated (0.68); PolyPhen benign (0.042); catalogued as rs778352818, COSV66139119; called by muse, mutect2, varscan2
- LRP5 | c.4841C>A p.S1614* | Nonsense Mutation (SNP) | VAF 9/30 reads (30%) | catalogued as rs1205077544, COSV99591681; called by muse, mutect2, varscan2
- LTBP1 | c.1732C>T p.Q578* (on ENST00000404816 / NM_206943.4; = p.Q252* on NM_000627.4) | Nonsense Mutation (SNP) | VAF 27/44 reads (61%) | catalogued as COSV100616741, COSV99062828; called by muse, mutect2, varscan2
- LTK | c.2398G>C p.E800Q | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.971); catalogued as COSV53029610, COSV99540874; called by muse, mutect2, varscan2
- LY9 | c.1226A>G p.E409G | Missense Mutation (SNP) | VAF 12/172 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54438517; called by muse, mutect2
- MACF1 | c.7973C>T p.S2658L | Missense Mutation (SNP) | VAF 17/71 reads (24%) | catalogued as COSV57148324; called by muse, mutect2, varscan2
- MAP3K4 | c.4747G>C p.E1583Q | Missense Mutation (SNP) | VAF 24/45 reads (53%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.998); catalogued as COSV62339396; called by muse, mutect2, varscan2
- MAPK8IP3 | c.1826G>T p.S609I | Missense Mutation (SNP) | VAF 28/57 reads (49%) | SIFT tolerated (0.09); PolyPhen benign (0.209); catalogued as COSV51728198; called by muse, mutect2, varscan2
- ME3 | c.333G>C p.M111I | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.02); catalogued as COSV60166454; called by muse, mutect2, varscan2
- MINPP1 | c.1033C>G p.Q345E | Missense Mutation (SNP) | VAF 58/99 reads (59%) | SIFT tolerated (0.23); PolyPhen benign (0.021); catalogued as COSV64354717; called by muse, mutect2, varscan2
- MMP21 | c.1557C>G p.F519L | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as COSV61764266; called by muse, mutect2, varscan2
- MROH2B | c.2966C>G p.S989C | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.847); catalogued as COSV68189996, COSV68190072, COSV68190262; called by muse, mutect2, varscan2
- MRPS30 | c.128G>A p.R43Q | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (0.2); PolyPhen benign (0.013); catalogued as rs760640875, COSV72361988; called by muse, mutect2, varscan2
- MTHFD1L | c.1518G>T p.R506S | Missense Mutation (SNP) | VAF 9/15 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1340066214, COSV66227912; called by muse, mutect2, varscan2
- MYH2 | c.356C>G p.S119* | Nonsense Mutation (SNP) | VAF 33/81 reads (41%) | catalogued as COSV99819700; called by muse, mutect2, varscan2
- NEURL4 | c.2909C>T p.S970F | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); catalogued as COSV59747742; called by muse, mutect2, varscan2
- NFATC4 | c.2277A>T p.R759S | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.879); catalogued as COSV51613136; called by muse, mutect2, varscan2
- NLRP4 | c.844G>A p.V282M | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.367); catalogued as rs745787067, COSV56717182; called by muse, mutect2, varscan2
- NME9 | c.890G>A p.S297N (on ENST00000333911 / NM_001349024.2; = p.S236N on NM_178130.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58623098; called by muse, mutect2, varscan2
- NSF | c.1486C>T p.Q496* | Nonsense Mutation (SNP) | VAF 20/58 reads (34%) | catalogued as COSV99833753; called by muse, mutect2, varscan2
- NXNL1 | c.16T>C p.S6P | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.149); catalogued as COSV57325384; called by muse, mutect2, varscan2
- ODF3L1 | c.40G>A p.A14T | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as COSV59820684; called by muse, mutect2, varscan2
- OR6Y1 | c.452G>A p.G151E | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.491); catalogued as rs747072395, COSV56931645; called by muse, mutect2, varscan2
- PCDH9 | c.2774C>A p.P925Q | Missense Mutation (SNP) | VAF 60/115 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.168); catalogued as COSV60596670; called by muse, mutect2, varscan2
- PLSCR2 | c.643G>T p.V215L (on ENST00000497985 / NM_001199978.1; = p.V142L on NM_020359.2) | Missense Mutation (SNP) | VAF 34/101 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.149); catalogued as COSV100367834, COSV60865150; called by muse, mutect2, varscan2
- PPM1E | c.2024C>T p.S675L | Missense Mutation (SNP) | VAF 25/134 reads (19%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.037); catalogued as COSV57581372; called by muse, mutect2, varscan2
- PPP4R4 | c.1901C>G p.S634C | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV58559044; called by muse, mutect2, varscan2
- PTPN4 | c.590G>A p.G197D | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV55310250; called by muse, mutect2, varscan2
- PTPRZ1 | c.1496C>G p.S499C | Missense Mutation (SNP) | VAF 24/93 reads (26%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.533); catalogued as COSV66446965; called by muse, mutect2, varscan2
- PTTG1IP | c.276G>T p.W92C | Missense Mutation (SNP) | VAF 30/55 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as rs1249067188, COSV58367159; called by muse, mutect2, varscan2
- RELA | c.419C>T p.P140L | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58016278; called by muse, mutect2, varscan2
- RORA | c.1019G>A p.R340H (on ENST00000335670 / NM_134261.3; = p.R365H on NM_002943.3) | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0.048); catalogued as rs1438949774, COSV55045150; called by muse, mutect2, varscan2
- SHC2 | c.758C>T p.A253V | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs759714454, COSV52749942; called by muse, mutect2, varscan2
- SHKBP1 | c.527G>A p.R176Q | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.102); catalogued as rs762052848, COSV52544142; called by muse, mutect2, varscan2
- SIX4 | c.1040G>A p.G347E | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); catalogued as COSV53671809; called by muse, mutect2, varscan2
- SLC22A12 | c.563C>T p.T188M | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs778952164, COSV60571864, COSV60572591; called by muse, mutect2, varscan2
- SLC29A1 | c.125G>A p.R42H | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.234); catalogued as rs193022001, COSV57578193; called by muse, mutect2, varscan2
- SPEM2 | c.446G>C p.R149T | Missense Mutation (SNP) | VAF 32/85 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.045); catalogued as COSV60367941; called by muse, mutect2, varscan2
- TOM1L1 | c.530C>T p.S177F | Missense Mutation (SNP) | VAF 38/165 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV61949803; called by muse, mutect2, varscan2
- TONSL | c.603_629del p.F202_T210del | In Frame Del (DEL) | VAF 12/30 reads (40%) | catalogued as COSV68049634; called by mutect2, pindel, varscan2
- TRRAP | c.5623G>A p.V1875M (on ENST00000359863 / NM_001244580.1; = p.V1857M on NM_003496.3) | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.557); catalogued as rs1554418714, COSV62851149, COSV62855835; called by muse, mutect2, varscan2
- VCAN | c.4230C>A p.Y1410* | Nonsense Mutation (SNP) | VAF 8/21 reads (38%) | catalogued as COSV99425250; called by muse, mutect2, varscan2
- VWA3A | c.2806C>T p.R936C | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT tolerated (0.32); PolyPhen benign (0.025); catalogued as rs377675023; called by muse, mutect2
- WDR17 | c.2312G>A p.S771N | Missense Mutation (SNP) | VAF 19/24 reads (79%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.985); catalogued as COSV54585674; called by muse, mutect2, varscan2
- XIRP1 | c.2077G>A p.V693M | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs548691510, COSV61141794; called by muse, mutect2, varscan2
- YEATS2 | c.1078C>T p.P360S | Missense Mutation (SNP) | VAF 50/143 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV59373260; called by muse, mutect2, varscan2
- ZFYVE26 | c.3140-1G>A p.X1047_splice | Splice Site (SNP) | VAF 23/81 reads (28%) | catalogued as COSV61334310; called by muse, mutect2, varscan2
- ZIK1 | c.541C>T p.R181W | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.153); catalogued as rs753153477, COSV56738729; called by muse, mutect2, varscan2
- ZNF202 | c.268G>A p.V90M | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1420775798, COSV60248877; called by muse, mutect2, varscan2
- ZNF420 | c.1853G>A p.R618K | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58492409; called by muse, mutect2, varscan2
- ZNF461 | c.1598_1603del p.H533_R534del | In Frame Del (DEL) | VAF 8/37 reads (22%) | catalogued as COSV64455569; called by mutect2, pindel
- ZNF521 | c.1715A>G p.N572S | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT tolerated (0.47); PolyPhen benign (0.068); catalogued as COSV64132712; called by muse, mutect2, varscan2
- ZNF585A | c.1582G>A p.G528R (on ENST00000292841 / NM_001288800.2; = p.G473R on NM_152655.3) | Missense Mutation (SNP) | VAF 29/155 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV53067609; called by muse, mutect2, varscan2
- ZNHIT1 | c.253C>T p.Q85* | Nonsense Mutation (SNP) | VAF 27/124 reads (22%) | catalogued as COSV100521976; called by muse, mutect2, varscan2
- ZSWIM8 | c.2650G>C p.E884Q | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV67135249; called by muse, mutect2, varscan2
- CDKN1A | c.248_255del p.R83Pfs*3 | Frame Shift Del (DEL) | VAF 7/29 reads (24%) | called by mutect2, pindel, varscan2
- COG3 | c.1720-36_1725del p.X574_splice | Splice Site (DEL) | VAF 8/39 reads (21%) | called by mutect2, pindel
- GUCA1B | c.187del p.R63Efs*20 | Frame Shift Del (DEL) | VAF 12/60 reads (20%) | called by mutect2, pindel, varscan2
- SLC9C1 | c.2989dup p.M997Nfs*21 | Frame Shift Ins (INS) | VAF 12/79 reads (15%) | called by mutect2, pindel, varscan2
- ACTL6B | c.945G>A p.S315= | Silent (SNP) | VAF 6/29 reads (21%) | catalogued as rs752954710, COSV50514236; called by muse, mutect2, varscan2
- AHNAK2 | c.11697C>T p.V3899= | Silent (SNP) | VAF 80/261 reads (31%) | catalogued as rs556940298, COSV100317969, COSV100318673, COSV60933304; called by muse, mutect2, varscan2
- BEND6 | c.255G>A p.R85= | Silent (SNP) | VAF 40/201 reads (20%) | catalogued as COSV66069025; called by muse, mutect2, varscan2
- C1orf112 | c.1135C>T p.L379= | Silent (SNP) | VAF 24/51 reads (47%) | catalogued as COSV53683440; called by muse, mutect2, varscan2
- CFAP74 | c.1209C>T p.C403= | Silent (SNP) | VAF 30/126 reads (24%) | catalogued as COSV54575018; called by mutect2, varscan2
- CHAF1A | c.2577G>A p.T859= | Silent (SNP) | VAF 15/72 reads (21%) | catalogued as COSV56676945; called by muse, mutect2, varscan2
- DCAF4 | c.306G>A p.E102= | Silent (SNP) | VAF 23/70 reads (33%) | catalogued as rs1352410688, COSV62320707; called by muse, mutect2, varscan2
- DNAH1 | c.654C>G p.L218= | Silent (SNP) | VAF 14/35 reads (40%) | catalogued as COSV70237557; called by muse, mutect2, varscan2
- EHMT1 | c.3024G>A p.R1008= | Silent (SNP) | VAF 8/28 reads (29%) | catalogued as COSV71778810; called by muse, mutect2, varscan2
- ERBB3 | c.3609G>A p.R1203= | Silent (SNP) | VAF 16/55 reads (29%) | catalogued as rs770761268, COSV57264837; called by muse, mutect2, varscan2
- FLII | c.288C>T p.V96= | Silent (SNP) | VAF 60/177 reads (34%) | catalogued as COSV58948580; called by muse, mutect2, varscan2
- GIMAP6 | c.486C>T p.F162= | Silent (SNP) | VAF 39/182 reads (21%) | catalogued as COSV61035055; called by muse, mutect2, varscan2
- GTF2H4 | c.783C>T p.F261= | Silent (SNP) | VAF 18/76 reads (24%) | catalogued as rs761255428, COSV52561508; called by muse, mutect2, varscan2
- HOMEZ | c.1335G>A p.L445= | Silent (SNP) | VAF 7/34 reads (21%) | catalogued as COSV100664053, COSV62538061; called by muse, mutect2, varscan2
- IGHG2 | c.225C>T p.N75= | Silent (SNP) | VAF 20/61 reads (33%) | called by muse, mutect2, varscan2
- KAT14 | c.1365G>A p.P455= | Silent (SNP) | VAF 8/41 reads (20%) | catalogued as rs149391936; called by muse, mutect2, varscan2
- KCTD13 | c.231G>A p.L77= | Silent (SNP) | VAF 14/133 reads (11%) | catalogued as COSV58161869; called by muse, mutect2
- KDM4D | c.1230A>C p.A410= | Silent (SNP) | VAF 15/50 reads (30%) | catalogued as COSV58636916; called by muse, mutect2, varscan2
- KIFC2 | c.1575C>G p.L525= | Silent (SNP) | VAF 10/38 reads (26%) | catalogued as rs772568227, COSV56763269; called by muse, mutect2, varscan2
- KSR2 | c.1788G>A p.V596= | Silent (SNP) | VAF 21/74 reads (28%) | catalogued as COSV56685378; called by muse, mutect2, varscan2
- LIMA1 | c.1723C>T p.L575= | Silent (SNP) | VAF 32/102 reads (31%) | catalogued as COSV57969061; called by muse, varscan2
- MAN2B1 | c.1509C>G p.L503= | Silent (SNP) | VAF 4/23 reads (17%) | catalogued as COSV99666833; called by muse, mutect2
- MFGE8 | c.513C>T p.F171= | Silent (SNP) | VAF 30/76 reads (39%) | catalogued as COSV51556591; called by muse, mutect2, varscan2
- MGAT4C | c.1008C>T p.D336= | Silent (SNP) | VAF 23/61 reads (38%) | catalogued as rs1293877675, COSV59838796; called by muse, mutect2, varscan2
- MIB2 | c.2235G>A p.K745= | Silent (SNP) | VAF 11/31 reads (35%) | catalogued as COSV61543572; called by muse, mutect2, varscan2
- MXRA5 | c.8172C>T p.I2724= | Silent (SNP) | VAF 28/44 reads (64%) | catalogued as COSV54253313; called by muse, mutect2, varscan2
- MYL2 | c.340C>T p.L114= | Silent (SNP) | VAF 35/45 reads (78%) | catalogued as COSV57408304; called by muse, mutect2, varscan2
- NET1 | c.288T>C p.A96= (on ENST00000355029 / NM_001047160.3; = p.A42= on NM_005863.5) | Silent (SNP) | VAF 43/148 reads (29%) | catalogued as COSV61792912; called by muse, mutect2, varscan2
- ORM1 | c.64T>C p.L22= | Silent (SNP) | VAF 25/83 reads (30%) | catalogued as rs1238138383, COSV52277992; called by muse, varscan2
- PADI1 | c.612C>T p.P204= | Silent (SNP) | VAF 24/76 reads (32%) | catalogued as COSV64939383; called by muse, mutect2, varscan2
- PIK3R4 | c.1341C>T p.L447= | Silent (SNP) | VAF 49/110 reads (45%) | catalogued as rs371432819; called by muse, mutect2, varscan2
- RASIP1 | c.2073C>T p.L691= | Silent (SNP) | VAF 7/48 reads (15%) | catalogued as COSV55808805; called by muse, mutect2, varscan2
- RIN2 | c.2655C>G p.L885= (on ENST00000255006 / NM_001242581.1; = p.L836= on NM_018993.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 35/56 reads (63%) | catalogued as COSV54795348; called by muse, mutect2, varscan2
- ROR2 | c.810C>T p.I270= | Silent (SNP) | VAF 6/10 reads (60%) | catalogued as rs756959301, COSV100995649; called by muse, varscan2
- SCARB2 | c.843C>T p.F281= | Silent (SNP) | VAF 32/70 reads (46%) | catalogued as COSV53670789; called by muse, mutect2, varscan2
- SEC31B | c.2106C>T p.C702= | Silent (SNP) | VAF 16/32 reads (50%) | catalogued as COSV64844292, COSV64845982; called by muse, mutect2, varscan2
- SEMA5A | c.2112G>A p.L704= | Silent (SNP) | VAF 30/199 reads (15%) | catalogued as rs1178742366, COSV66803958, COSV66807064; called by muse, mutect2, varscan2
- SLC25A28 | c.279C>T p.I93= | Silent (SNP) | VAF 7/12 reads (58%) | catalogued as rs1214928181, COSV100979604; called by muse, mutect2, varscan2
- ST6GALNAC2 | c.597C>T p.F199= | Silent (SNP) | VAF 28/111 reads (25%) | catalogued as COSV56572889; called by muse, mutect2, varscan2
- SUGP2 | c.195C>T p.L65= | Silent (SNP) | VAF 8/30 reads (27%) | catalogued as COSV100431722; called by muse, mutect2
- TBCB | c.42C>T p.F14= | Silent (SNP) | VAF 8/17 reads (47%) | catalogued as rs1458857794, COSV52900851; called by muse, mutect2, varscan2
- TET1 | c.1506G>A p.Q502= | Silent (SNP) | VAF 21/31 reads (68%) | catalogued as COSV65390130; called by muse, mutect2, varscan2
- TGFBI | c.654G>C p.L218= | Silent (SNP) | VAF 19/47 reads (40%) | catalogued as COSV59354880; called by muse, mutect2, varscan2
- TMEM255B | c.980G>A p.*327= | Silent (SNP) | VAF 45/157 reads (29%) | catalogued as COSV100944105; called by muse, mutect2, varscan2
- TRIM39 | c.888C>T p.I296= | Silent (SNP) | VAF 8/49 reads (16%) | catalogued as COSV64956565; called by muse, mutect2, varscan2
- TRIM6 | c.234G>A p.V78= | Silent (SNP) | VAF 16/51 reads (31%) | catalogued as COSV53479597; called by muse, mutect2, varscan2
- TSC2 | c.3327G>A p.P1109= | Silent (SNP) | VAF 5/12 reads (42%) | catalogued as rs45478393, CD052521, COSV99553418; ClinVar: benign / likely benign / not provided; called by muse, varscan2
- TTN | c.40416C>A p.V13472= (on ENST00000591111; = p.V6048= on NM_003319.4) | Silent (SNP) | VAF 33/53 reads (62%) | catalogued as rs1420238951, COSV60103963; called by muse, mutect2, varscan2
- UBAP2L | c.237C>T p.V79= | Silent (SNP) | VAF 21/170 reads (12%) | catalogued as rs1262635879, COSV55182543; called by muse, mutect2, varscan2
- USP6NL | c.636C>G p.L212= | Silent (SNP) | VAF 31/87 reads (36%) | catalogued as COSV53216473; called by muse, mutect2, varscan2
- VCAN | c.8562C>T p.V2854= | Silent (SNP) | VAF 17/44 reads (39%) | catalogued as rs781758939, COSV54118505; called by muse, mutect2, varscan2
- VN1R2 | c.417C>T p.I139= | Silent (SNP) | VAF 26/157 reads (17%) | catalogued as rs778685542, COSV59038177; called by muse, mutect2, varscan2
- ZC3H10 | c.696G>A p.P232= | Silent (SNP) | VAF 17/52 reads (33%) | catalogued as rs371248458, COSV57769477; called by muse, mutect2, varscan2
- AC244258.1 | n.315C>T | RNA (SNP) | VAF 19/59 reads (32%) | called by muse, mutect2, varscan2
- IRAK2 | c.-1C>T | 5'UTR (SNP) | VAF 10/20 reads (50%) | catalogued as rs1290218435, COSV99843854; called by muse, mutect2, varscan2
- PDE4D | c.455+124829G>A | Intron (SNP) | VAF 31/65 reads (48%) | catalogued as COSV58983811; called by muse, mutect2, varscan2
- RAD9B | c.1234+10C>T | Intron (SNP) | VAF 12/41 reads (29%) | catalogued as COSV62827466; called by muse, mutect2, varscan2
- RN7SL176P | chr12:100158044 G>A | 3'Flank (SNP) | VAF 6/25 reads (24%) | catalogued as rs1488956813; called by muse, mutect2, varscan2
